Somatic mutation profile of tumor specimen TCGA-D7-A747-01A (aliquot TCGA-D7-A747-01A-22D-A33T-08) from TCGA case TCGA-D7-A747, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 57.3 years (20,923 days).
Specimen TCGA-D7-A747-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acf8ef80-17cf-49f1-b3e1-577f36657494.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-A747-10A (Blood Derived Normal), aliquot TCGA-D7-A747-10A-21D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b67a5536-fa3e-4f70-82a3-866af747dbf1

The open-access MAF lists 92 somatic variants for this specimen: 77 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 12, 3'UTR 1, 5'UTR 1, Intron 1, Nonsense Mutation 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS20 | c.4513G>T p.V1505F | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV101238790; called by muse, mutect2, varscan2
- ANKLE1 | c.943G>C p.V315L (on ENST00000394458; = p.V261L on NM_152363.6) | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.011); catalogued as COSV100845692; called by muse, mutect2, varscan2
- ARHGAP20 | c.2113G>C p.E705Q | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV52810725, COSV99502993; called by muse, mutect2
- BICC1 | c.1467T>G p.S489R | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.462); catalogued as COSV99570127; called by muse, mutect2
- C7 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV100495329; called by muse, mutect2, varscan2
- CACNA2D3 | c.3116A>C p.K1039T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as COSV55556688; called by muse, mutect2
- CAPG | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs761175093, COSV55708121; called by muse, mutect2, varscan2
- CCDC120 | c.1430G>T p.R477L | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV100896521; called by muse, mutect2
- CCSER1 | c.720C>G p.S240R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100387631; called by muse, mutect2, varscan2
- CDC16 | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV99372655; called by muse, mutect2
- CERCAM | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 21/283 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs959170698, COSV100863815; called by muse, mutect2
- CGNL1 | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.764); catalogued as COSV99847339; called by muse, mutect2, varscan2
- CNOT1 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs369419200; called by muse, mutect2, varscan2
- COL27A1 | c.4069C>T p.R1357C | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745478632, COSV100620697; called by muse, mutect2, varscan2
- COL5A3 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1232352415, COSV53414512; called by muse, mutect2
- CSGALNACT1 | c.387C>A p.D129E | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.035); catalogued as COSV100174464; called by muse, mutect2
- CTNNB1 | c.1864G>C p.A622P | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100845982; called by muse, mutect2
- CYP46A1 | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs757381529, COSV99952405; called by muse, mutect2, varscan2
- CYP7B1 | c.995A>G p.K332R | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV59582892, COSV59590977; called by muse, mutect2
- DEF6 | c.843C>G p.F281L | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100359119; called by muse, mutect2
- DENND2C | c.2312A>C p.K771T (on ENST00000393274 / NM_001256404.2; = p.K714T on NM_198459.4) | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV101283878; called by muse, mutect2, varscan2
- ELAVL2 | c.293A>T p.N98I | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as COSV99805243; called by muse, mutect2, varscan2
- ELOA2 | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs376146729, COSV99795803; called by muse, mutect2
- EPCAM | c.866C>A p.S289Y | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.862); catalogued as COSV99763989; called by muse, mutect2
- ETV6 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as rs1398054657, CM1511687, COSV56765831; called by muse, mutect2
- FBRS | c.1201G>C p.A401P (on ENST00000287468; = p.A921P on NM_001105079.3) | Missense Mutation (SNP) | VAF 18/311 reads (6%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV99788782; called by muse, mutect2
- FSIP2 | c.15944T>G p.L5315R | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100554623, COSV58105441; called by muse, mutect2, varscan2
- GDF6 | c.285C>A p.H95Q | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54623242, COSV99747541; called by muse, mutect2
- GRIP1 | c.687A>C p.E229D | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV99667819; called by muse, mutect2
- GRPR | c.532T>G p.F178V | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100977619; called by muse, mutect2, varscan2
- GUCY2F | c.3230A>C p.D1077A | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99484426; called by muse, mutect2
- HTR3A | c.955A>C p.S319R | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100248239, COSV100248462; called by muse, mutect2
- IL13RA2 | c.354A>C p.E118D | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV99682832; called by muse, mutect2, varscan2
- IRX4 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as COSV99180760, COSV99182001; called by muse, mutect2
- ITIH2 | c.207A>C p.Q69H | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.667); catalogued as COSV100623127; called by muse, mutect2
- KIF2B | c.1218A>G p.I406M | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV99274571; called by muse, mutect2
- KRT72 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as rs748635916, COSV99537019; called by muse, mutect2, varscan2
- LRP12 | c.248A>C p.N83T | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV99407076; called by muse, mutect2
- LRP1B | c.12611A>C p.N4204T | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV101251572, COSV67238657; called by muse, mutect2, varscan2
- LZTS3 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100232104; called by muse, mutect2
- MC4R | c.921A>C p.Q307H | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as COSV100235843; called by muse, mutect2
- MROH2B | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1407999857, COSV68182448; called by muse, mutect2, varscan2
- MYLK | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100658444; called by muse, mutect2
- MYT1L | c.1418T>G p.L473R | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV67707737, COSV67734158; called by muse, mutect2, varscan2
- MYT1L | c.608A>T p.K203M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101218522, COSV67710505, COSV67719870; called by muse, mutect2, varscan2
- NCOA2 | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as rs1314506996, COSV101475901; called by muse, mutect2
- OLFM3 | c.255A>C p.Q85H (on ENST00000338858 / NM_001288821.1; = p.Q65H on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100128821; called by muse, mutect2, varscan2
- PTCH1 | c.4024C>T p.R1342C | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.328); catalogued as rs781539921, COSV59464556; ClinVar: likely benign / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2
- PTDSS1 | c.140G>A p.S47N | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV99749512; called by muse, mutect2
- PXDN | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.906); catalogued as COSV99412100; called by muse, mutect2, varscan2
- RAX | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99900169; called by muse, mutect2
- RP1 | c.3797A>G p.K1266R | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV99606117; called by muse, mutect2
- RPS6KA5 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as rs746195386, COSV100002010; called by muse, mutect2, varscan2
- RTL3 | c.279T>G p.D93E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100329492; called by muse, mutect2, varscan2
- SEC14L5 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs774309210, COSV99228522; called by muse, mutect2, varscan2
- SETBP1 | c.4310A>G p.K1437R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99029963, COSV99951829, COSV99955519; called by muse, mutect2, varscan2
- SGIP1 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.036); catalogued as COSV99390301; called by muse, mutect2, varscan2
- SIGLEC1 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1206559395, COSV99163220; called by muse, mutect2, varscan2
- SLC12A7 | c.1063T>C p.Y355H | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99369233; called by muse, mutect2
- SORBS2 | c.2515C>T p.P839S (on ENST00000284776 / NM_021069.5; = p.P405S on NM_003603.6) | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs376740726; called by muse, mutect2
- SORCS3 | c.3151G>T p.G1051C | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100864411; called by muse, mutect2
- SPIRE1 | c.1364G>A p.R455K (on ENST00000409402 / NM_001128626.2; = p.R441K on NM_020148.3) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100563293; called by muse, mutect2, varscan2
- SYNE1 | c.20033A>C p.H6678P (on ENST00000367255 / NM_182961.4; = p.H6607P on NM_033071.3) | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768271480, COSV99551654; called by muse, mutect2
- SYNE1 | c.1337T>C p.L446P (on ENST00000367255 / NM_182961.4; = p.L453P on NM_033071.3) | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV54904935, COSV99551663; called by muse, mutect2
- TCTE1 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as rs373958880; called by muse, mutect2
- TFPI2 | c.338A>C p.Y113S | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55989790, COSV99746512; called by muse, mutect2
- TIMP1 | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); catalogued as COSV99512074; called by muse, mutect2
- TMPRSS15 | c.2494T>G p.L832V | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as rs1231579914, COSV53039182, COSV53041945; called by muse, mutect2, varscan2
- TTBK2 | c.3109G>T p.E1037* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99141068; called by muse, mutect2, varscan2
- UBE2Q2 | c.803T>C p.I268T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99143183; called by muse, mutect2, varscan2
- UNC79 | c.1113T>G p.C371W (on ENST00000393151 / NM_001346218.2; = p.C194W on NM_020818.5) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99825526, COSV99828811; called by muse, mutect2, varscan2
- VIM | c.1169A>C p.K390T | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99812849; called by muse, mutect2
- ZNF761 | c.1657A>G p.K553E | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100483247; called by muse, mutect2, varscan2
- ZNF880 | c.858_860del p.H287del | In Frame Del (DEL) | VAF 4/36 reads (11%) | catalogued as rs1568665055; called by pindel, varscan2
- PCDHA3 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.3); called by muse, mutect2
- WWC3 | c.2681del p.R894Qfs*90 | Frame Shift Del (DEL) | VAF 56/159 reads (35%) | called by mutect2, pindel, varscan2
- ARHGEF26 | c.453C>T p.N151= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV62844258; called by muse, mutect2, varscan2
- CADPS | c.3366C>T p.T1122= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as COSV99335649; called by muse, mutect2
- CSNK1A1L | c.216C>T p.G72= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as COSV101131063; called by muse, mutect2
- KIRREL2 | c.1809C>T p.Y603= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as COSV99383480; called by muse, mutect2
- KRTAP11-1 | c.468G>A p.V156= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV100190462; called by muse, mutect2
- MYBL2 | c.2088C>T p.T696= | Silent (SNP) | VAF 25/304 reads (8%) | catalogued as rs200062988, COSV99405955; called by muse, mutect2
- PROS1 | c.1692C>T p.A564= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV101260207; called by muse, mutect2, varscan2
- ROBO2 | c.372G>A p.A124= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as rs763736763, COSV59901240; ClinVar: uncertain significance; called by muse, mutect2
- SOX11 | c.639G>A p.A213= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100430705; called by muse, mutect2, varscan2
- TBX5 | c.745A>C p.R249= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV100090367, COSV59863219; called by muse, mutect2
- WFDC3 | c.522G>C p.L174= | Silent (SNP) | VAF 13/155 reads (8%) | catalogued as COSV99714385; called by muse, mutect2
- ZNF285 | c.483C>T p.N161= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as COSV58411472; called by muse, mutect2, varscan2
- CYP8B1 | c.*2C>T | 3'UTR (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100296015; called by muse, mutect2, varscan2
- H3C10 | c.-1C>T | 5'UTR (SNP) | VAF 9/96 reads (9%) | catalogued as rs554898930, COSV100297466; called by muse, mutect2, varscan2
- NALCN | c.1765-4857T>G | Intron (SNP) | VAF 36/120 reads (30%) | catalogued as COSV51922869, COSV51925386, COSV51970703; called by muse, varscan2
